Somatic mutation profile of tumor specimen MBCproject_0227_T2_WES (aliquot MBCproject_0227_T2_WES_1) from CMI case MBCproject_0227, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.2 years (16,155 days).
Specimen MBCproject_0227_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 817b7c88-f865-4bb4-9bc6-815b83ce079a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0227_SALIVA (Saliva), aliquot MBCproject_0227_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fce8c7d-4894-48ee-a9a5-1ea643302427

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 3 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, In Frame Del 6, Intron 4, Frame Shift Del 4, Silent 3, 3'UTR 3, Nonstop Mutation 1, 5'Flank 1, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- TP53 | c.613T>G p.Y205D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CFAP57 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1416841642; called by muse, mutect2, varscan2
- CHRNA2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747493891, COSV99532384; called by muse, mutect2, varscan2
- EFCAB2 | c.810A>G p.*270Wext*5 (on ENST00000366522; = p.*134Wext*5 on NM_001143943.1) | Nonstop Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs1218866620, COSV63659826; called by muse, varscan2
- KDM1A | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV56500216; called by muse, mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, mutect2, varscan2
- PRRC2C | c.1687C>A p.Q563K (on ENST00000367742; = p.Q561K on NM_015172.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs868576903; called by mutect2, varscan2
- SLC18A1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs372918747; called by mutect2, varscan2
- TBX3 | c.886A>G p.N296D (on ENST00000257566 / NM_016569.4; = p.N276D on NM_005996.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV57469032, COSV57474113; called by mutect2, varscan2
- THAP3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs547107923; called by muse, varscan2
- ADAMTS9 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG13 | c.1326+4del p.X442_splice | Splice Site (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- AMIGO2 | c.1218_1219dup p.V407Afs*14 | Frame Shift Ins (INS) | VAF 3/9 reads (33%) | called by mutect2, varscan2
- CBX2 | c.1302_1320del p.S434Rfs*19 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- CCL14 | c.80_100del p.R27_E34delinsQ (on ENST00000618404 / NM_032963.4; = p.G43_S49del on NM_032962.4) | In Frame Del (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- CLDN16 | c.126_158del p.K42_T52del | In Frame Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- CLINT1 | c.1485_1502del p.K497_S502del | In Frame Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- CLPX | c.402del p.F134Lfs*13 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- COL6A2 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXQ1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-73 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); called by muse, varscan2
- KIF21A | c.848_857del p.R283Lfs*22 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- NEXMIF | c.730T>G p.C244G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR6K2 | c.893T>A p.I298K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- PHF3 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, varscan2
- PHF3 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); called by muse, varscan2
- PHF3 | c.2407G>C p.E803Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, varscan2
- SRSF4 | c.1122_1151del p.S374_K383del | In Frame Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, varscan2*
- TBX1 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TPCN1 | c.912_941del p.S305_L314del | In Frame Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- XRN1 | c.889_897del p.P298_L300del | In Frame Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- ZNF175 | c.291_295+3del | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- MAP2K3 | c.768C>A p.I256= (on ENST00000342679 / NM_145109.3; = p.I227= on NM_002756.4) | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- OR6K2 | c.219T>C p.Y73= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1175372899; called by mutect2, varscan2
- SLC16A4 | c.852G>C p.S284= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV63917145; called by mutect2, varscan2
- CNGA1 | c.-15+10412A>G | Intron (SNP) | VAF 14/71 reads (20%) | catalogued as rs1393881531, COSV62054954; called by muse, varscan2
- HFE | c.*2177A>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs1460397415; called by muse, mutect2, varscan2
- LAIR2 | c.-6_-1del | 5'UTR (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- MAEA | c.579+1083_579+1095del | Intron (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- MCFD2 | chr2:46917277 G>C | 5'Flank (SNP) | VAF 8/20 reads (40%) | catalogued as rs1368617587, COSV60177774; called by mutect2, varscan2
- PARP8 | c.147-8249C>T | Intron (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- SHROOM4 | c.*1378T>G | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as rs1557245541; called by muse, varscan2
- SSH1 | c.111-13624A>G | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs1382553106, COSV58468320; called by muse, mutect2, varscan2
- TBXA2R | c.*701G>C | 3'UTR (SNP) | VAF 8/64 reads (13%) | catalogued as rs5759, COSV59258217; called by mutect2, varscan2
- ZNF90 | chr19:20121323 T>C | 3'Flank (SNP) | VAF 6/36 reads (17%) | catalogued as rs1555706533; called by mutect2, varscan2
